CCDI case PBCKYY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/c559811b-a13d-4773-96a4-05f82a23fedf

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Neurofibroma, NOS: ICD-O-3 morphology code: 9540/0; Tissue or organ of origin: Spinal cord; Age at diagnosis: 15.6 years (5,690 days).

Biospecimens (1 sample)
- Sample 0DUHHX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
